Somatic mutation profile of tumor specimen TCGA-V4-A9ES-01A (aliquot TCGA-V4-A9ES-01A-11D-A39W-08) from TCGA case TCGA-V4-A9ES, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.9 years (20,054 days).
Specimen TCGA-V4-A9ES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e70b2b17-56a1-46bc-a581-b6b5f9027cdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9ES-10A (Blood Derived Normal), aliquot TCGA-V4-A9ES-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5582e2f-11a3-472a-83ac-2921f2c112a1

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 12.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 60/104 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs397514698, CM1412391, COSV54106047, COSV54107425; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CAP2 | c.944C>A p.S315Y | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs888404839, COSV57729706; called by muse, mutect2, varscan2
- CBX5 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV52935568; called by muse, mutect2, varscan2
- DEPDC5 | c.1858A>G p.T620A | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV56690850; called by muse, mutect2, varscan2
- M1AP | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as COSV51842671, COSV51847831; called by muse, mutect2, varscan2
- OR2D3 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1454070399, COSV53491594; called by muse, mutect2, varscan2
- TRPM6 | c.3361C>G p.H1121D | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV62502764; called by muse, mutect2, varscan2
- TTLL13P | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs754001735, COSV60036038; called by muse, mutect2, varscan2
- ZNF560 | c.1233A>T p.K411N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV56865256; called by muse, mutect2, varscan2
- BCOR | c.2152G>C p.D718H | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXD4L6 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
